Surgical pathology report (de-identified scan), TCGA case TCGA-NA-A4R0, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site Duke University, specimen TCGA-NA-A4R0-01A (Primary Tumor).

[page 1 of 2]
Surg Path

CLINICAL HISTORY:

Malignant neoplasm corpus uteri. Per e-browser: endometrial cancer. Vaginal cuff study.

GROSS EXAMINATION:

A. "Omentum", received fresh and placed in formalin [REDACTED] is a 5 x 5 x 3.5 cm aggregate of fibroadipose tissue, which contains two areas of induration measuring up to 4.5 cm. Representative sections of these indurated areas are submitted in A1-3.

B. "Uterus, cervix, bilateral tubes and ovaries", received fresh and placed in formalin [REDACTED] is a 58 gm, 7 x 5 x 3 cm uterus with a 2.2 cm cervix. The posterior endometrium discloses a 3 x 2.5 cm area of polypoid thickening, which invades 1.1 cm into a 1.5 cm thick myometrium in its deepest portion. No additional abnormalities are noted within the endomyometrium. The uterine serosa and cervix are free of tumor and grossly unremarkable. The right uterine adnexa consists of a 2 x 1 x 1 cm ovary and 5 cm long x 0.5 cm in diameter fimbriated fallopian tube. No abnormalities are noted within the right uterine adnexa. The left uterine adnexa consists of a 5.5 cm long x 0.4 cm in diameter fimbriated fallopian tube and a 1.5 x 0.8 x 0.4 cm ovary. No abnormalities are identified within the left uterine adnexa.

BLOCK SUMMARY:

- B1-4 representative endometrial mass (with deepest invasion in B1-2)
- B5- representative uninvolved unaffected endomyometrium
- B6- anterior cervix
- B7- posterior cervix
- B8- representative right uterine adnexa
- B9- representative left uterine adnexa

ICD-0-3

Carcinosarcoma 8980/3
Site: Fundus uteri C54.3
Capted AWS 1/6/13

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: Hysterosalpingo-oophorectomy and partial omentectomy

PATHOLOGIC STAGE (AJCC 7th Edition): pT3c pNX pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. OMENTUM, PARTIAL RESECTION:

ADIPOSE TISSUE WITH EXTENSIVE POORLY DIFFERENTIATED ADENOCARCINOMA.

SEE COMMENT.

MAXIMUM TUMOR SIZE: 4.5 CM.

[page 2 of 2]
B. UTERUS, CERVIX, BILATERAL TUBES AND OVARIES:

UTERUS: 58 GRAMS

CARCINOSARCOMA OF THE ENDOMETRIUM:

TUMOR SITE: POSTERIOR FUNDUS.

HISTOLOGIC TYPE: CARCINOSARCOMA WITH HETEROLOGOUS ELEMENTS

FIGO GRADE: 3.

TUMOR SIZE: 3.0 X 2.5 CM.

MAXIMUM DEPTH OF MYOMETRIAL INVASION: 0.6 CM, IN A 1.6 THICK WALL.

LYMPHATIC/VASCULAR INVASION: PRESENT.

ADJACENT NON-NEOPLASTIC ENDOMETRIUM: NOT HYPERPLASTIC.

REMAINING MYOMETRIUM: NO PATHOLOGIC DIAGNOSIS.

CERVIX: NEGATIVE FOR CARCINOMA.

SEROSA: NEGATIVE FOR CARCINOMA.

SPECIMEN MARGINS: NOT INVOLVED.

OVARIES, RIGHT AND LEFT: POSITIVE FOR POORLY DIFFERENTIATED ADENOCARCINOMA
(MAINLY ON SEROSAL ASPECT).

FALLOPIAN TUBES, RIGHT AND LEFT: NEGATIVE FOR CARCINOMA.

COMMENT: In part B, the uterine tumor in most areas has the appearance of poorly differentiated adenocarcinoma. Many foci resemble serous papillary carcinoma, with some foci appearing endometrioid ; many other areas appear to be undifferentiated carcinoma. In addition, there are focal areas of sarcomatous differentiation including spindle shaped cells and cartilage. The tumor in the omentum mainly assumes the characteristics of a poorly differentiated adenocarcinoma.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Performed by:

Reviewed In: [Signature]	Date Reviewed: 10/17/12	

Source: NCI Genomic Data Commons file aa0beea2-c606-4923-bcbe-1f55b98d9310 (TCGA-NA-A4R0.E835F67C-2B15-4896-B167-6BFE0CEA836A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).